Somatic mutation profile of tumor specimen TCGA-85-8350-01A (aliquot TCGA-85-8350-01A-11D-2293-08) from TCGA case TCGA-85-8350, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 61.7 years (22,526 days).
Specimen TCGA-85-8350-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88a75667-1f6b-42a2-8ac3-24d33860f275.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8350-10A (Blood Derived Normal), aliquot TCGA-85-8350-10A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9de10a13-3f55-4625-b0c9-2704e5d76a18

The open-access MAF lists 340 somatic variants for this specimen: 247 protein-altering or splice-affecting, 88 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 207, Silent 88, Nonsense Mutation 21, Splice Site 8, Frame Shift Del 4, Splice Region 4, Intron 3, In Frame Del 1, 5'UTR 1, 3'Flank 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 11/100 reads (11%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- CDKN2A | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 9/24 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.3806G>T p.R1269I | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV99287861; called by muse, mutect2, varscan2
- ABCB5 | c.1777G>A p.V593M (on ENST00000404938 / NM_001163941.2; = p.V148M on NM_178559.6) | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.382); catalogued as COSV51706398, COSV99327376; called by muse, mutect2, varscan2
- ABCC2 | c.2351T>G p.L784R | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100966386; called by muse, mutect2, varscan2
- ABLIM1 | c.229A>C p.S77R | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.024); catalogued as COSV99521414; called by muse, mutect2, varscan2
- ABTB1 | c.1335C>A p.F445L (on ENST00000232744 / NM_172027.3; = p.F303L on NM_032548.3) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV99229562; called by muse, mutect2
- ACACB | c.6045G>T p.K2015N | Missense Mutation (SNP) | VAF 117/416 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV100622313; called by muse, mutect2, varscan2
- ADAM19 | c.1202G>T p.G401V | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57433129, COSV99976106; called by muse, mutect2, varscan2
- ADGRB3 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV65401825; called by muse, mutect2, varscan2
- AFF2 | c.615G>T p.Q205H | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as COSV100648834; called by muse, mutect2, varscan2
- AFF2 | c.1879G>C p.G627R | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99661910; called by muse, mutect2, varscan2
- ANKS1B | c.1759G>T p.D587Y | Missense Mutation (SNP) | VAF 103/318 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs866244804, COSV100245739, COSV61365156; called by muse, mutect2, varscan2
- APCS | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV54817515, COSV54817666; called by muse, mutect2, varscan2
- APOL4 | c.186G>T p.W62C (on ENST00000352371 / NM_145660.2; = p.W59C on NM_030643.4) | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100113160; called by muse, mutect2, varscan2
- ASPM | c.9121A>G p.R3041G | Missense Mutation (SNP) | VAF 61/219 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99659498; called by muse, mutect2, varscan2
- ASPM | c.3776G>T p.R1259M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99659499; called by muse, mutect2, varscan2
- ATN1 | c.2677C>T p.H893Y | Missense Mutation (SNP) | VAF 107/311 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100755650; called by muse, mutect2, varscan2
- ATP12A | c.2356A>G p.N786D | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99516992; called by muse, mutect2, varscan2
- ATP6AP2 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV101011440; called by muse, mutect2, varscan2
- BPTF | c.6176C>G p.T2059S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100074034; called by muse, mutect2, varscan2
- C15orf40 | c.342G>T p.R114S | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV100417263; called by muse, mutect2, varscan2
- C4A | c.2684G>T p.R895L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.245); catalogued as COSV101418296; called by muse, mutect2
- CACNA1C | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as rs786205769, COSV100215278; ClinVar: uncertain significance; called by muse, mutect2
- CCDC136 | c.2939G>T p.G980V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV99922152; called by muse, mutect2, varscan2
- CCDC39 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs753991733, COSV99867163; called by muse, mutect2, varscan2
- CD44 | c.1195C>G p.Q399E | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV99555414; called by muse, mutect2, varscan2
- CDH10 | c.1684T>G p.Y562D | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100050042; called by muse, mutect2, varscan2
- CDH12 | c.1832G>C p.G611A | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV101201360, COSV66395997; called by muse, mutect2, varscan2
- CEACAM21 | c.308C>A p.P103H | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.32); catalogued as COSV99494326; called by muse, mutect2, varscan2
- CFAP70 | c.3039G>C p.E1013D | Missense Mutation (SNP) | VAF 86/367 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV100160171; called by muse, varscan2
- CLPTM1L | c.610G>C p.G204R | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV100306806; called by muse, mutect2, varscan2
- COG6 | c.695-1G>A p.X232_splice | Splice Site (SNP) | VAF 8/92 reads (9%) | catalogued as COSV100742578; called by muse, mutect2
- COL20A1 | c.2117G>A p.G706D | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100489899; called by muse, mutect2, varscan2
- COL6A1 | c.358del p.V120Sfs*28 | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | catalogued as COSV62612876, COSV62614791; called by mutect2, pindel, varscan2
- COL9A3 | c.1225G>A p.G409S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406567877, COSV100673303; called by muse, mutect2
- CP | c.992C>G p.P331R | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.886); catalogued as COSV99223712; called by muse, mutect2, varscan2
- CPA1 | c.1217C>A p.A406E | Missense Mutation (SNP) | VAF 105/389 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CM139205, COSV99163215; called by muse, mutect2, varscan2
- CPT1A | c.2045G>T p.W682L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99680568; called by muse, mutect2, varscan2
- CRB1 | c.2750C>A p.T917K | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV100957659; called by muse, mutect2, varscan2
- CRISPLD1 | c.518G>T p.W173L | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100081573; called by muse, mutect2, varscan2
- CSF2RA | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 21/143 reads (15%) | catalogued as rs1316466248, COSV62624552; called by muse, mutect2, varscan2
- DAXX | c.1760C>T p.S587F | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs760084261, COSV99801440; called by muse, mutect2, varscan2
- DAXX | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV99801443; called by muse, mutect2, varscan2
- DAXX | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV56471697, COSV99801446; called by muse, mutect2, varscan2
- DCC | c.3593T>A p.L1198Q | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV101472327; called by muse, mutect2, varscan2
- DCTN1 | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV100720861, COSV62620923; called by muse, mutect2
- DDX17 | c.1757G>A p.R586Q | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.735); catalogued as rs748322707, COSV99318048; called by muse, mutect2, varscan2
- DDX18 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.115); catalogued as COSV99604280; called by muse, mutect2, varscan2
- DDX39B | c.212-1G>T p.X71_splice | Splice Site (SNP) | VAF 8/170 reads (5%) | catalogued as COSV100795155; called by muse, mutect2
- DGKI | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99932427; called by muse, mutect2, varscan2
- DOCK2 | c.3361A>G p.R1121G | Missense Mutation (SNP) | VAF 50/347 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.073); catalogued as COSV99910287, COSV99916463; called by muse, mutect2, varscan2
- DPP6 | c.2247C>A p.A749= (on ENST00000377770 / NM_001364500.2; = p.A687= on NM_001936.5) | Splice Region (SNP) | VAF 34/330 reads (10%) | catalogued as COSV100123044; called by muse, mutect2, varscan2
- DSC3 | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100844497; called by muse, mutect2, varscan2
- EHD3 | c.242A>T p.Q81L | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV100434614; called by muse, mutect2, varscan2
- EPHA3 | c.2744C>A p.T915K | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100342795; called by muse, mutect2, varscan2
- ERICH3 | c.1545A>T p.E515D | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.255); catalogued as COSV100443385; called by muse, mutect2, varscan2
- ERICH3 | c.1124G>C p.R375T | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100443387; called by muse, mutect2, varscan2
- FAM47A | c.1510C>T p.L504F | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as rs917350837, COSV100649683, COSV60500355; called by muse, varscan2
- FCSK | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 46/230 reads (20%) | catalogued as rs772939990, COSV55367786; called by muse, mutect2, varscan2
- FGD5 | c.1505G>T p.G502V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99547231; called by muse, mutect2, varscan2
- FLNC | c.766C>A p.Q256K | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV100367621; called by muse, mutect2, varscan2
- FMN2 | c.3500del p.P1167Lfs*108 | Frame Shift Del (DEL) | VAF 21/102 reads (21%) | catalogued as COSV60431269; called by mutect2, pindel, varscan2
- FMO5 | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV54205932, COSV99566671; called by muse, mutect2, varscan2
- FOCAD | c.2098C>G p.Q700E | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100620030; called by muse, mutect2, varscan2
- FPGT | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as COSV100907056; called by muse, mutect2, varscan2
- GABRG1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99777361, COSV99777845; called by muse, mutect2, varscan2
- GALNT13 | c.843A>C p.R281S | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.09); catalogued as COSV101222192; called by muse, mutect2, varscan2
- GAP43 | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV100525278; called by muse, mutect2, varscan2
- GAS2L3 | c.464G>T p.R155I | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99902679; called by muse, mutect2, varscan2
- GFRAL | c.345G>A p.W115* | Nonsense Mutation (SNP) | VAF 14/93 reads (15%) | catalogued as COSV100474601; called by muse, mutect2, varscan2
- GLI2 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); catalogued as COSV100082316; called by muse, mutect2, varscan2
- GNA15 | c.302A>G p.Q101R | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV99505038; called by muse, mutect2, varscan2
- GPATCH8 | c.1496G>A p.S499N | Missense Mutation (SNP) | VAF 71/257 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100132462; called by muse, mutect2, varscan2
- GPER1 | c.65C>A p.A22E | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99866734; called by muse, mutect2, varscan2
- GTF2A1 | c.260A>G p.H87R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs1372784951, COSV99993304; called by muse, mutect2, varscan2
- H1-2 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1440238210, COSV100642243; called by muse, mutect2, varscan2
- HEATR5B | c.4723G>T p.G1575C | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.428); catalogued as rs368900081, COSV99248207; called by muse, mutect2, varscan2
- HELZ | c.1241T>C p.I414T | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as rs753397557, COSV100698510; called by muse, mutect2, varscan2
- HIF3A | c.1965dup p.G656Rfs*14 (on ENST00000377670 / NM_152795.4; = p.G587Rfs*14 on NM_022462.4) | Frame Shift Ins (INS) | VAF 87/228 reads (38%) | catalogued as rs773128936; called by mutect2, pindel, varscan2
- HLA-DQA2 | c.739G>T p.G247C | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100890660; called by muse, mutect2, varscan2
- HMGCS2 | c.780G>T p.Q260H | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV101024679; called by muse, mutect2, varscan2
- HSD17B1 | c.236G>C p.R79P | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.562); catalogued as COSV99864552, COSV99864631; called by muse, mutect2, varscan2
- IFIH1 | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); catalogued as rs748544874, COSV99718389; called by muse, mutect2, varscan2
- IGF2R | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100806754; called by muse, mutect2, varscan2
- IGHV3-72 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 86/243 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs377465637; called by muse, mutect2, varscan2
- IGLV7-43 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1276673791; called by muse, mutect2, varscan2
- IL7R | c.537G>T p.T179= | Splice Region (SNP) | VAF 35/54 reads (65%) | catalogued as COSV100285886, COSV57409931; called by muse, mutect2, varscan2
- JAKMIP1 | c.244A>C p.K82Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.234); catalogued as COSV99288613; called by muse, mutect2, varscan2
- KANK4 | c.352G>C p.A118P | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100587007; called by muse, mutect2
- KCNF1 | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); catalogued as COSV99705527; called by muse, mutect2, varscan2
- KCNK9 | c.658T>A p.Y220N | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100270333; called by muse, mutect2, varscan2
- KDR | c.3838C>A p.P1280T | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV99816707; called by muse, mutect2, varscan2
- KLHL1 | c.733G>T p.V245F | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV64773530; called by muse, mutect2, varscan2
- KLK15 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100032499; called by muse, mutect2, varscan2
- KRT73 | c.385C>G p.R129G | Missense Mutation (SNP) | VAF 61/259 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV59838883, COSV99988265; called by muse, mutect2, varscan2
- KRTAP4-4 | c.78C>A p.C26* | Nonsense Mutation (SNP) | VAF 29/184 reads (16%) | catalogued as COSV101180529; called by muse, mutect2, varscan2
- LMBRD1 | c.964G>T p.A322S (on ENST00000649011; = p.A300S on NM_018368.4) | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.573); catalogued as rs754013620, COSV100992434; called by muse, mutect2, varscan2
- LMNTD2 | c.1835C>A p.A612E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99529465; called by muse, varscan2
- LMTK3 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.777); catalogued as COSV99539963; called by muse, mutect2, varscan2
- LRAT | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100312003; called by muse, mutect2, varscan2
- LRIT2 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 47/254 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV100928288; called by muse, mutect2, varscan2
- LRP1 | c.3784C>T p.R1262C | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV99674385; called by muse, mutect2, varscan2
- LRP1B | c.5722G>T p.G1908* | Nonsense Mutation (SNP) | VAF 30/122 reads (25%) | catalogued as COSV101252387; called by muse, mutect2, varscan2
- LRRFIP1 | c.1686G>T p.L562F (on ENST00000392000 / NM_001137552.2; = p.L538F on NM_004735.4) | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV99790363; called by muse, mutect2, varscan2
- MAGEB6 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV66872119, COSV66873247; called by muse, mutect2, varscan2
- MAMDC4 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99915391; called by muse, mutect2, varscan2
- MARCHF4 | c.1118C>G p.S373C | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.45); catalogued as COSV99814064; called by muse, mutect2, varscan2
- MCMDC2 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as COSV100551676; called by muse, mutect2, varscan2
- MCOLN3 | c.714T>A p.C238* | Nonsense Mutation (SNP) | VAF 62/424 reads (15%) | catalogued as COSV100352567; called by muse, mutect2, varscan2
- MED12L | c.2134C>G p.P712A | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56370234, COSV99851498; called by muse, mutect2, varscan2
- MGAM | c.3100C>A p.P1034T | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.463); catalogued as COSV101527370; called by muse, mutect2, varscan2
- MGAT5 | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV99924064; called by muse, mutect2, varscan2
- MKI67 | c.4396G>A p.D1466N | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs765703005, COSV100896157; called by muse, mutect2, varscan2
- MNT | c.1274C>A p.P425Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99437929; called by muse, mutect2, varscan2
- MOXD1 | c.1224G>A p.M408I | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV100381239; called by muse, mutect2
- MS4A1 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100619266, COSV61941897; called by muse, mutect2, varscan2
- MSH4 | c.1559G>T p.G520V | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV54201829; called by muse, mutect2, varscan2
- MT3 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.378); catalogued as COSV99570464; called by muse, varscan2
- MUC5B | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs770066523, COSV71592310; called by muse, mutect2, varscan2
- MVP | c.845G>T p.C282F | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV100651475; called by muse, mutect2, varscan2
- MYO18B | c.984G>T p.W328C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.723); catalogued as COSV100122579; called by muse, mutect2, varscan2
- NBAS | c.5872C>G p.L1958V | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.279); catalogued as COSV99867102; called by muse, mutect2, varscan2
- NCAN | c.185C>A p.T62N | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as rs773438807, COSV99386529; called by muse, mutect2, varscan2
- NCKAP1L | c.261C>A p.F87L | Missense Mutation (SNP) | VAF 98/301 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV53205780, COSV99514452; called by muse, mutect2, varscan2
- NCOR2 | c.4342G>T p.E1448* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100656829; called by muse, mutect2, varscan2
- NKD1 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs142743935; called by muse, mutect2, varscan2
- NLRP12 | c.2278G>T p.E760* | Nonsense Mutation (SNP) | VAF 83/287 reads (29%) | catalogued as COSV100144836; called by muse, mutect2, varscan2
- NPAS4 | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100214773; called by muse, mutect2, varscan2
- NPSR1 | c.146A>T p.K49M | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV100705728; called by muse, mutect2, varscan2
- NXPH1 | c.749A>C p.K250T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101339565; called by muse, mutect2, varscan2
- OGDH | c.2848A>C p.N950H | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV99758294; called by muse, mutect2, varscan2
- OLFML2B | c.949+1G>T p.X317_splice | Splice Site (SNP) | VAF 31/141 reads (22%) | catalogued as COSV54194970, COSV99668018; called by muse, mutect2, varscan2
- OLIG3 | c.422T>A p.L141Q | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100880216; called by muse, mutect2, varscan2
- OR10K2 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.097); catalogued as COSV100149383; called by muse, mutect2, varscan2
- OR51D1 | c.871A>T p.T291S | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV100712347; called by muse, mutect2, varscan2
- OR56B1 | c.554A>C p.H185P | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100402530; called by muse, mutect2, varscan2
- OR5H2 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100788626; called by muse, mutect2, varscan2
- OR5M8 | c.410A>T p.K137M | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV100510539, COSV59116454; called by muse, mutect2, varscan2
- OR6C74 | c.929C>A p.S310* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100667665, COSV59607354; called by muse, mutect2, varscan2
- OTOF | c.4362+1G>A p.X1454_splice (on ENST00000272371 / NM_194248.3; = p.X687_splice on NM_004802.4) | Splice Site (SNP) | VAF 8/82 reads (10%) | catalogued as rs1274464930, COSV99716499; called by muse, mutect2
- PADI6 | c.1818G>C p.K606N | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV100639890; called by muse, mutect2, varscan2
- PASK | c.1463G>T p.G488V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99298628; called by muse, mutect2, varscan2
- PBXIP1 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as COSV100870008; called by muse, mutect2, varscan2
- PCDHA5 | c.1621G>T p.V541L | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.019); catalogued as rs17844295, COSV100972090; called by muse, mutect2, varscan2
- PCDHB16 | c.19C>A p.H7N | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as rs782459939, COSV99501057; called by muse, mutect2, varscan2
- PCDHB2 | c.1537G>T p.G513C | Missense Mutation (SNP) | VAF 103/323 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50575111, COSV99164156; called by muse, mutect2, varscan2
- PCDHB6 | c.1396C>A p.L466M | Missense Mutation (SNP) | VAF 122/504 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99169909; called by muse, mutect2, varscan2
- PCDHB9 | c.2185G>T p.E729* | Nonsense Mutation (SNP) | VAF 70/391 reads (18%) | catalogued as COSV53380994; called by muse, mutect2, varscan2
- PCDHGA2 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.025); catalogued as rs993292970, COSV53927820, COSV99533996; called by muse, mutect2, varscan2
- PCDHGA3 | c.2385G>T p.Q795H | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV53981752, COSV99530525; called by muse, mutect2, varscan2
- PCDHGA3 | c.2386G>T p.D796Y | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.474); catalogued as COSV99530528; called by muse, mutect2, varscan2
- PDZRN3 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV99727342; called by muse, mutect2, varscan2
- PHACTR1 | c.1568G>C p.S523T | Missense Mutation (SNP) | VAF 66/270 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV100275448; called by muse, mutect2, varscan2
- PLCH1 | c.2758C>T p.R920C (on ENST00000340059 / NM_001130960.2; = p.R912C on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs536782697, COSV100395544, COSV58199616; called by muse, mutect2, varscan2
- PLEKHG4B | c.3387G>T p.M1129I (on ENST00000283426; = p.M1485I on NM_052909.5) | Missense Mutation (SNP) | VAF 316/416 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV99359779; called by muse, mutect2, varscan2
- PLXNA4 | c.4662G>T p.E1554D | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV100322435; called by muse, mutect2, varscan2
- POGLUT1 | c.579-1G>T p.X193_splice | Splice Site (SNP) | VAF 21/132 reads (16%) | catalogued as COSV99809403; called by muse, mutect2, varscan2
- POTEE | c.849A>T p.Q283H | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.19); catalogued as COSV100386945; called by muse, mutect2
- POU3F2 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV100098960; called by muse, mutect2, varscan2
- PPFIA4 | c.881T>A p.M294K | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV99829487; called by muse, mutect2, varscan2
- PPP2R2A | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 23/100 reads (23%) | catalogued as COSV60096644; called by muse, mutect2, varscan2
- PREX2 | c.4432G>C p.A1478P | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV99904979; called by muse, mutect2, varscan2
- PRR35 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53465751, COSV99551815; called by muse, mutect2, varscan2
- PSG9 | c.1244-1G>T p.X415_splice | Splice Site (SNP) | VAF 19/173 reads (11%) | catalogued as COSV99392040; called by muse, mutect2, varscan2
- PTBP1 | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV100608348; called by muse, mutect2, varscan2
- PTGFR | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.267); catalogued as COSV100882238; called by muse, mutect2, varscan2
- PTPRT | c.883C>G p.P295A | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100625195; called by muse, mutect2, varscan2
- PTPRZ1 | c.6253-2A>G p.X2085_splice | Splice Site (SNP) | VAF 66/260 reads (25%) | catalogued as COSV101099525; called by muse, mutect2, varscan2
- RAB27A | c.16T>G p.Y6D | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100389154; called by muse, mutect2, varscan2
- RAPGEF2 | c.510G>T p.L170= | Splice Region (SNP) | VAF 32/103 reads (31%) | catalogued as COSV100030501; called by muse, mutect2, varscan2
- RASGEF1C | c.719G>A p.C240Y | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.492); catalogued as COSV100745564; called by muse, mutect2, varscan2
- RB1CC1 | c.3686A>G p.Q1229R | Missense Mutation (SNP) | VAF 62/290 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as rs951480668, COSV99206074; called by muse, mutect2, varscan2
- RIN3 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99378477, COSV99379745; called by muse, mutect2, varscan2
- RP1L1 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as rs370486258, COSV101222939; called by muse, mutect2, varscan2
- RUNX1T1 | c.1810C>A p.R604S (on ENST00000265814 / NM_001198628.1; = p.R577S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV56155283, COSV99749432; called by muse, mutect2, varscan2
- RYR1 | c.6185G>A p.R2062H | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs368235923; called by muse, mutect2, varscan2
- SAGE1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0.168); catalogued as COSV100186628; called by muse, mutect2, varscan2
- SAMD7 | c.839A>C p.E280A | Missense Mutation (SNP) | VAF 22/317 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.162); catalogued as COSV100156741; called by muse, mutect2
- SAR1A | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV100951544; called by muse, mutect2, varscan2
- SELENOI | c.1040T>A p.L347Q | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99564163; called by muse, mutect2, varscan2
- SELPLG | c.1167C>A p.S389R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV99947229; called by muse, mutect2, varscan2
- SEMA4F | c.1772C>T p.S591L | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100335716; called by muse, mutect2, varscan2
- SENP7 | c.733A>T p.N245Y | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV100052409; called by muse, mutect2, varscan2
- SHANK2 | c.3011C>A p.A1004D | Missense Mutation (SNP) | VAF 12/285 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV99572206; called by muse, mutect2
- SHB | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 79/233 reads (34%) | catalogued as COSV100891039, COSV66621449; called by muse, mutect2, varscan2
- SI | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 204/289 reads (71%) | SIFT tolerated (0.51); PolyPhen benign (0.185); catalogued as rs141620268; called by muse, mutect2, varscan2
- SIDT1 | c.2272C>A p.L758I | Missense Mutation (SNP) | VAF 113/306 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.672); catalogued as COSV99333123; called by muse, mutect2, varscan2
- SLC16A14 | c.1491A>G p.I497M | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs756430391, COSV99725166; called by muse, mutect2, varscan2
- SLC35F1 | c.548C>A p.A183D | Missense Mutation (SNP) | VAF 106/397 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as COSV100837511; called by muse, mutect2, varscan2
- SLC36A2 | c.1282G>T p.V428F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV100078900; called by muse, mutect2, varscan2
- SLC39A10 | c.1912A>T p.K638* | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | catalogued as COSV100660486; called by muse, mutect2
- SLC5A9 | c.222G>C p.M74I | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.292); catalogued as COSV99361334; called by muse, mutect2, varscan2
- SLC6A18 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99721989; called by muse, mutect2, varscan2
- SMC1B | c.512A>C p.K171T | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.835); catalogued as COSV100662940; called by muse, mutect2
- SPESP1 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99533288; called by muse, mutect2, varscan2
- SPTBN2 | c.2792A>G p.N931S | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1345097576, COSV59456550; called by muse, mutect2, varscan2
- SRCAP | c.974G>T p.R325L | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV99349254; called by muse, mutect2, varscan2
- ST6GAL2 | c.1292C>G p.P431R | Missense Mutation (SNP) | VAF 21/215 reads (10%) | PolyPhen possibly damaging (0.45); catalogued as rs754838335, COSV100699521; called by muse, mutect2, varscan2
- ST8SIA3 | c.879T>A p.H293Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | PolyPhen benign (0.001); catalogued as COSV100129290; called by muse, mutect2, varscan2
- STAB2 | c.5086A>T p.T1696S | Missense Mutation (SNP) | VAF 69/237 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV101185617; called by muse, mutect2, varscan2
- STRN | c.303G>T p.R101S | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99814936; called by muse, mutect2, varscan2
- SUPT20H | c.1780G>T p.A594S (on ENST00000350612 / NM_001014286.3; = p.A595S on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV100634539; called by muse, mutect2, varscan2
- SYNE1 | c.26288G>C p.C8763S (on ENST00000367255 / NM_182961.4; = p.C8715S on NM_033071.3) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV99553026; called by muse, mutect2, varscan2
- SYNE1 | c.15062A>G p.N5021S (on ENST00000367255 / NM_182961.4; = p.N4950S on NM_033071.3) | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99553038; called by muse, mutect2, varscan2
- TAF2 | c.3238A>G p.S1080G | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100978402; called by muse, mutect2, varscan2
- TCTN2 | c.986A>T p.E329V | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as COSV100315086; called by muse, mutect2, varscan2
- TECTA | c.959G>C p.S320T | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as COSV99878569; called by muse, mutect2, varscan2
- TNFRSF10D | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.173); catalogued as COSV100441589; called by muse, mutect2, varscan2
- TNRC6C | c.2575G>A p.G859S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100049453; called by muse, mutect2, varscan2
- TRAF7 | c.82-1G>T p.X28_splice | Splice Site (SNP) | VAF 20/96 reads (21%) | catalogued as COSV100399055; called by muse, mutect2, varscan2
- TRH | c.238C>A p.L80I | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.053); catalogued as COSV100234724, COSV57014521; called by muse, mutect2, varscan2
- TRMO | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.09); catalogued as COSV100795990, COSV63336771; called by muse, mutect2, varscan2
- TSPYL2 | c.356C>G p.P119R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.216); catalogued as COSV100212020; called by muse, mutect2, varscan2
- TWIST1 | c.571A>T p.R191W | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99642970, COSV99643154; called by muse, varscan2
- UBQLN1 | c.1360A>G p.M454V | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as rs756116588, COSV99973126; called by muse, mutect2, varscan2
- UGT3A2 | c.1074G>C p.L358= | Splice Region (SNP) | VAF 13/192 reads (7%) | catalogued as COSV99235972; called by muse, mutect2
- UNC5A | c.2359G>T p.D787Y | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99457793; called by muse, mutect2, varscan2
- USH2A | c.13070C>A p.S4357* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV100228882; called by muse, mutect2, varscan2
- USH2A | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV100228887; called by muse, mutect2, varscan2
- UTRN | c.3460G>T p.E1154* | Nonsense Mutation (SNP) | VAF 25/170 reads (15%) | catalogued as COSV100839550; called by muse, mutect2, varscan2
- VCAN | c.8539A>G p.S2847G | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1373649150, COSV99424619; called by muse, mutect2, varscan2
- VPS13C | c.1963G>T p.D655Y (on ENST00000644861 / NM_020821.3; = p.D612Y on NM_017684.5) | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99827084; called by muse, mutect2, varscan2
- WRN | c.4078G>T p.D1360Y | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV99988249, COSV99989700; called by muse, mutect2, varscan2
- YAP1 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.866); catalogued as COSV99176026; called by muse, mutect2, varscan2
- ZBTB22 | c.748G>T p.G250* | Nonsense Mutation (SNP) | VAF 25/83 reads (30%) | catalogued as COSV99801437; called by muse, mutect2, varscan2
- ZBTB22 | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99801438; called by muse, mutect2, varscan2
- ZBTB39 | c.785C>T p.T262I | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100267900; called by muse, mutect2, varscan2
- ZFHX4 | c.9223G>C p.G3075R | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99255998; called by muse, mutect2, varscan2
- ZIK1 | c.1107C>G p.H369Q | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100277353, COSV100277654; called by muse, mutect2, varscan2
- ZNF100 | c.294G>C p.K98N | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV99973722; called by muse, mutect2
- ZNF292 | c.4313A>T p.Q1438L | Missense Mutation (SNP) | VAF 75/292 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV100369759; called by muse, mutect2, varscan2
- ZNF33B | c.1171G>T p.G391W | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100847582; called by muse, mutect2, varscan2
- ZNF37A | c.1543A>G p.R515G | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1386606419, COSV100697265; called by muse, mutect2, varscan2
- ZNF462 | c.247G>T p.G83* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV52937542, COSV99470760; called by muse, mutect2, varscan2
- ZNF626 | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.358); catalogued as COSV101656945; called by muse, mutect2
- ZNF99 | c.2435C>G p.T812S | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV101233698; called by muse, mutect2
- FCGBP | c.4584_4585del p.P1529Hfs*35 | Frame Shift Del (DEL) | VAF 13/85 reads (15%) | called by mutect2, varscan2
- GSTT2B | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by mutect2, varscan2
- IGKV2D-30 | c.137G>T p.S46I | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- KRTAP4-4 | c.79C>G p.Q27E | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PRSS3 | c.247G>T p.G83* (on ENST00000361005 / NM_007343.4; = p.G191* on NM_002771.3) | Nonsense Mutation (SNP) | VAF 50/201 reads (25%) | called by muse, mutect2, varscan2
- SPEN | c.2565_2567del p.N855del | In Frame Del (DEL) | VAF 21/115 reads (18%) | called by pindel, varscan2
- TP53 | c.619_634del p.D207Ffs*35 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | called by mutect2, pindel, varscan2
- TRAV14DV4 | c.257T>A p.L86* | Nonsense Mutation (SNP) | VAF 86/178 reads (48%) | called by muse, mutect2, varscan2
- TRAV8-6 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 90/208 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRBV2 | c.21C>A p.C7* | Nonsense Mutation (SNP) | VAF 14/116 reads (12%) | called by muse, mutect2, varscan2
- ABCA13 | c.5886C>T p.V1962= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV101329923; called by muse, mutect2, varscan2
- ABCC5 | c.1008A>C p.A336= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV55596144, COSV99656373; called by muse, mutect2, varscan2
- ABCD1 | c.1260C>T p.H420= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs782066367, COSV54387999; called by muse, mutect2, varscan2
- ABCG2 | c.1347G>C p.V449= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99418454; called by muse, mutect2, varscan2
- ACTR3B | c.1026G>T p.V342= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV99753577; called by muse, mutect2, varscan2
- ARMC5 | c.2694G>T p.R898= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99192320; called by muse, mutect2, varscan2
- AVPR1B | c.513T>A p.I171= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV100899310; called by muse, mutect2, varscan2
- BGN | c.225G>A p.Q75= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100525079; called by muse, mutect2, varscan2
- CASZ1 | c.1086C>A p.A362= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as COSV100680736; called by muse, mutect2, varscan2
- CCNA1 | c.105C>T p.F35= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99714309; called by muse, mutect2, varscan2
- CDH10 | c.1473G>A p.V491= | Silent (SNP) | VAF 10/214 reads (5%) | catalogued as COSV100050044, COSV100051760; called by muse, mutect2
- CFAP70 | c.2892T>C p.N964= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as rs780336023, COSV100160172; called by muse, varscan2
- CHIT1 | c.1326G>A p.A442= | Silent (SNP) | VAF 54/252 reads (21%) | catalogued as rs186594769, COSV55147899; called by muse, mutect2, varscan2
- CHST1 | c.1125C>A p.A375= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV100345965; called by muse, mutect2
- CSMD3 | c.8196A>G p.L2732= | Silent (SNP) | VAF 35/133 reads (26%) | catalogued as rs750713893, COSV52102468; called by muse, mutect2, varscan2
- CYP20A1 | c.642T>G p.L214= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100618999; called by muse, mutect2, varscan2
- DNAH5 | c.10707T>C p.D3569= | Silent (SNP) | VAF 190/275 reads (69%) | catalogued as COSV99444909; called by muse, mutect2, varscan2
- DOCK2 | c.4059C>A p.P1353= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as COSV99910288; called by muse, mutect2, varscan2
- DRC7 | c.528C>A p.T176= | Silent (SNP) | VAF 33/145 reads (23%) | catalogued as COSV100395364; called by muse, mutect2, varscan2
- FAM13B | c.822G>T p.L274= | Silent (SNP) | VAF 43/225 reads (19%) | catalogued as COSV99220957; called by muse, mutect2, varscan2
- FER1L6 | c.2100C>T p.N700= | Silent (SNP) | VAF 43/194 reads (22%) | catalogued as COSV101205442; called by muse, mutect2, varscan2
- FREM2 | c.4986G>A p.K1662= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV99746760; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.582G>A p.L194= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV100374336; called by muse, mutect2, varscan2
- GLB1L | c.1437G>A p.G479= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV99850236; called by muse, mutect2, varscan2
- GPAM | c.1683A>T p.T561= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV100788105; called by muse, mutect2, varscan2
- GRIN2D | c.1854G>T p.T618= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV99615810; called by muse, mutect2, varscan2
- GTF2E1 | c.1319G>A p.*440= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV99381722; called by muse, mutect2, varscan2
- HERC1 | c.13164G>A p.A4388= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs752398916, COSV101496317; called by muse, mutect2
- HTR5A | c.780G>C p.T260= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV99839426; called by muse, mutect2, varscan2
- HYAL4 | c.892C>T p.L298= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs1421010757, COSV99772049; called by muse, mutect2, varscan2
- IFT20 | c.99G>A p.L33= | Silent (SNP) | VAF 46/163 reads (28%) | catalogued as COSV99880176; called by muse, mutect2, varscan2
- IGHV2-26 | c.99C>A p.P33= | Silent (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- IQSEC2 | c.2115C>T p.S705= (on ENST00000642864 / NM_001111125.3; = p.S500= on NM_015075.2) | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as COSV100944728; called by muse, mutect2, varscan2
- KCNE3 | c.216G>C p.V72= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as COSV100035523; called by muse, mutect2, varscan2
- KCNF1 | c.1215C>T p.I405= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV99705528; called by muse, mutect2, varscan2
- LRP2 | c.5889C>A p.P1963= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV99786507; called by muse, mutect2, varscan2
- MCF2L | c.2694C>T p.A898= (on ENST00000375608; = p.A866= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs1013566442, COSV99995455; called by muse, mutect2, varscan2
- MCM6 | c.171G>A p.E57= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV99918736; called by muse, mutect2
- MS4A10 | c.342C>A p.T114= | Silent (SNP) | VAF 54/213 reads (25%) | catalogued as COSV100382201; called by muse, mutect2, varscan2
- MSH6 | c.3603C>T p.L1201= | Silent (SNP) | VAF 15/277 reads (5%) | catalogued as rs761458936, COSV52278724, COSV99315033; ClinVar: likely benign; called by muse, mutect2
- MYBL2 | c.1731C>T p.S577= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99405999; called by muse, varscan2
- NELL1 | c.2361C>G p.P787= | Silent (SNP) | VAF 24/201 reads (12%) | called by muse, mutect2, varscan2
- NOD2 | c.2550A>G p.L850= | Silent (SNP) | VAF 66/300 reads (22%) | catalogued as rs768823670, COSV100318209; called by muse, mutect2, varscan2
- NRXN3 | c.1938G>A p.Q646= (on ENST00000335750 / NM_001330195.2; = p.Q273= on NM_004796.6) | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV100200675; called by muse, mutect2, varscan2
- OR10T2 | c.300C>G p.T100= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100554813, COSV100554979; called by muse, mutect2, varscan2
- OR1D5 | c.498G>T p.V166= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV101643406; called by muse, mutect2, varscan2
- OR4C13 | c.6G>T p.A2= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as COSV101634138, COSV73648614; called by muse, mutect2, varscan2
- OR4D11 | c.810C>A p.A270= | Silent (SNP) | VAF 34/309 reads (11%) | catalogued as COSV100506460; called by muse, mutect2, varscan2
- OR6C75 | c.732A>T p.I244= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as COSV100595241; called by muse, mutect2, varscan2
- OR6F1 | c.501C>A p.S167= | Silent (SNP) | VAF 30/148 reads (20%) | catalogued as COSV100128939, COSV57467244; called by muse, mutect2, varscan2
- OTOGL | c.4995A>C p.I1665= (on ENST00000547103; = p.I1656= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 126/486 reads (26%) | catalogued as COSV100086677; called by muse, mutect2, varscan2
- PCDHA11 | c.2103C>A p.I701= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as COSV100247567, COSV56554595; called by muse, mutect2, varscan2
- PCDHGA9 | c.1911G>T p.A637= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV53995926; called by muse, mutect2, varscan2
- PCLO | c.2121G>T p.V707= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV100427325, COSV61644214; called by muse, mutect2
- PHF3 | c.699A>G p.G233= | Silent (SNP) | VAF 48/201 reads (24%) | catalogued as COSV100012872; called by muse, mutect2, varscan2
- PIK3R4 | c.3432C>T p.I1144= | Silent (SNP) | VAF 25/152 reads (16%) | catalogued as COSV100768201; called by muse, mutect2, varscan2
- PKD2L2 | c.1299T>G p.V433= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV99295975; called by muse, mutect2, varscan2
- PPM1K | c.609A>T p.V203= | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as COSV99900836; called by muse, mutect2, varscan2
- PRDM1 | c.426G>T p.G142= | Silent (SNP) | VAF 15/145 reads (10%) | catalogued as COSV100958539; called by muse, mutect2, varscan2
- PRDM10 | c.1485G>A p.Q495= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV100456550; called by muse, mutect2, varscan2
- PRRC2C | c.2310A>G p.K770= (on ENST00000367742; = p.K768= on NM_015172.4) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1203740170, COSV100144644; called by muse, mutect2
- PTPN22 | c.1696C>T p.L566= (on ENST00000359785 / NM_001193431.2; = p.L511= on NM_012411.5) | Silent (SNP) | VAF 10/156 reads (6%) | catalogued as COSV63086399; called by muse, mutect2
- RELN | c.4323G>C p.V1441= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV100632402; called by muse, mutect2, varscan2
- RGS1 | c.393T>C p.C131= | Silent (SNP) | VAF 24/200 reads (12%) | catalogued as rs1455458143, COSV100817385, COSV66505842; called by muse, mutect2, varscan2
- SACS | c.12804C>T p.F4268= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV66539938; called by muse, mutect2, varscan2
- SCN1A | c.3609A>G p.Q1203= (on ENST00000303395 / NM_001202435.3; = p.Q1192= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/199 reads (29%) | catalogued as CD084213, COSV100319265; called by muse, mutect2, varscan2
- SIDT1 | c.2271C>A p.A757= | Silent (SNP) | VAF 115/309 reads (37%) | catalogued as COSV99333118; called by muse, mutect2, varscan2
- SLC28A2 | c.675A>G p.V225= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as COSV100754617; called by muse, mutect2, varscan2
- SLC2A2 | c.913C>T p.L305= | Silent (SNP) | VAF 16/472 reads (3%) | catalogued as COSV100049064, COSV58589151; called by muse, mutect2
- SLC36A3 | c.1293G>A p.K431= | Silent (SNP) | VAF 60/187 reads (32%) | catalogued as COSV100077337, COSV58856527; called by muse, mutect2, varscan2
- SLCO4C1 | c.2091A>C p.T697= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as COSV100194470; called by muse, mutect2, varscan2
- SNCAIP | c.1551G>A p.S517= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs370073718, COSV99747113; called by muse, mutect2, varscan2
- SPTA1 | c.3513T>A p.L1171= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100934224; called by muse, mutect2, varscan2
- STK17B | c.585C>T p.I195= | Silent (SNP) | VAF 66/187 reads (35%) | catalogued as COSV99825977; called by muse, mutect2, varscan2
- THRAP3 | c.1476G>A p.E492= | Silent (SNP) | VAF 20/143 reads (14%) | catalogued as COSV100663169; called by muse, mutect2, varscan2
- THSD7B | c.1758C>T p.P586= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as COSV99744284; called by muse, mutect2
- TNN | c.3675C>A p.A1225= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV99511061; called by muse, mutect2, varscan2
- TSKS | c.774G>T p.P258= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs757213011; called by muse, varscan2
- UBR2 | c.1122C>T p.F374= | Silent (SNP) | VAF 9/216 reads (4%) | catalogued as COSV100867358; called by muse, mutect2
- UBR4 | c.13050T>C p.F4350= | Silent (SNP) | VAF 38/136 reads (28%) | catalogued as COSV100920196; called by muse, mutect2, varscan2
- UNC5D | c.990G>T p.R330= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as COSV99772064; called by muse, mutect2, varscan2
- WDR17 | c.834C>T p.P278= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as COSV99706773; called by muse, mutect2, varscan2
- ZNF382 | c.1500C>T p.A500= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV99497435; called by muse, mutect2
- ZNF536 | c.813G>C p.A271= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100834651, COSV62818663; called by muse, mutect2
- ZNF569 | c.546C>G p.V182= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV100386327; called by muse, mutect2, varscan2
- ZNF570 | c.1092G>C p.G364= | Silent (SNP) | VAF 58/132 reads (44%) | catalogued as COSV100356012, COSV100356050; called by muse, mutect2, varscan2
- ZNF808 | c.1776G>A p.E592= | Silent (SNP) | VAF 11/163 reads (7%) | catalogued as COSV100707780; called by muse, mutect2
- ZNF831 | c.2488C>T p.L830= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs1468821225, COSV100925757; called by muse, mutect2, varscan2
- ADGRF2 | chr6:47687004 C>T | 3'Flank (SNP) | VAF 22/180 reads (12%) | catalogued as rs1490618596, COSV99730690; called by muse, mutect2, varscan2
- TRIM31 | c.-1C>T | 5'UTR (SNP) | VAF 15/100 reads (15%) | catalogued as COSV100946741, COSV100946830; called by muse, mutect2, varscan2
- TTN | c.10361-4659C>A | Intron (SNP) | VAF 19/66 reads (29%) | catalogued as COSV100593863, COSV100636005; called by muse, mutect2, varscan2
- ZFHX3 | c.-533+256G>A | Intron (SNP) | VAF 44/145 reads (30%) | catalogued as COSV101637447; called by muse, mutect2, varscan2
- ZNF211 | c.90+444G>T | Intron (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99560014; called by muse, mutect2, varscan2
